Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5693, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5693-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: KIDNEY, RIGHT, RADICAL NEPHRECTOMY -

- A. MULTIFOCAL RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE, WELL- TO MODERATELY-DIFFERENTIATED (see comment).
- B. FUHRMAN NUCLEAR GRADE IS 2 OF 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASMS IS 4.8 CM AND 2.2 CM, RESPECTIVELY.
- D. BOTH NEOPLASMS ARE CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- I. THE ADRENAL GLAND IS NOT SUBMITTED.
- J. PATHOLOGIC STAGE: pT1b Nx Mx.
- K. HISTOLOGIC GRADE = G2.

PART 2: GALLBLADDER, CHOLECYSTECTOMY - CHRONIC CHOLELITHIASIS.

COMMENT:

Two tumor nodules were identified: a solid, clear cell renal cell carcinoma measuring 4.8 cm and a cystic clear cell renal cell carcinoma measuring 2.2 cm which was separate by 0.3 cm from the previous. The larger, solid neoplasm is composed of cells with predominant Fuhrman nuclear grade 1, and focal areas of Fuhrman nuclear grade 2. The cystic neoplasm is characterized by a thick capsule and scant neoplastic cells lining the cyst wall, these cells are Fuhrman nuclear grade 1. These two neoplasms are interpreted to be separate synchronous tumors.

SYNOPTIC - PRIMARY KIDNEY/RENAL PELVIS/URETER TUMORS

- | | | |
|---|----------|---|
| A. Side: 1 | 1. Right | 2. Left |
| B. Location: 1 | | |
| 1. Kidney (parenchyma - cortex/medulla) | | 3. Ureter |
| 2. Kidney (pelvis) | | 4. Kidney and ureter |
| C. Procedure: 3 | | |
| 1. Partial nephrectomy | | 4. Ureterectomy |
| 2. Simple nephrectomy | | 5. Other |
| 3. Radical nephrectomy | | |
| D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 4.8 cm | | |
| E. Type of malignant neoplasm: 1 | | |
| 1. Renal cell carcinoma, clear cell type
(includes non-papillary granular cell RCC) | | 11. Urothelial carcinoma, small cell/neuroendocrine carcinoma |
| 2. Renal cell carcinoma, chromophil cell type
(papillary RCC, no clear cell component) | | 12. Urothelial carcinoma, mixed |
| 3. Renal cell carcinoma, chromophobe cell type | | 13. Juxtaglomerular cell tumor |
| 4. Renal cell carcinoma, oncocytic | | 14. Wilms' tumor |
| 5. Renal cell carcinoma, sarcomatoid | | 15. Rhabdoid tumor |
| 6. Collecting duct carcinoma | | 16. Clear cell sarcoma |
| 7. Urothelial carcinoma, TCCa
(non-invasive) | | 17. Congenital mesoblastic nephroma |
| 8. Urothelial carcinoma, TCCa
(invasive ± in-situ) | | 18. Sarcoma (non-clear cell) |
| 9. Urothelial carcinoma, squamous carcinoma | | 19. Lymphoma/leukemia |
| 10. Urothelial carcinoma, adenocarcinoma | | 20. Other |
| F. Histologic grade | | |
| F1. Fuhrman grade (for RCC; grades 1-4): 2 | | |
| F2. Ash grade (grade 1-4): # | | |
| F3. WHO grade (grade 1-3): # (for TCCa) | | |
| F4. # | | |
| 1. LMP | 2. LG | 3. HG |
| F5. Other malignant neoplasms (grades 1-3): # | | |
| G. Non-neoplastic and other conditions: # / # / # / # | | |
| 1. Glomerulopathy | | |
| 2. Interstitial nephritis | | |
| 3. Pyelonephritis | | |
| 4. Nephrolithiasis | | |
| 5. Papillary necrosis | | |
| 6. Chronic parenchymal disease | | |
| 7. Other | | |
| H. Margins of resection: 2 | | |
| I. Mitotic activity: 0 per 10 high power fields | | |
| J. Angiolymphatic invasion | | |
| J1. Macroscopic (e.g., renal vein thrombus): 2 | | |
| J2. Microscopic: 2 | | |
| K. Number of positive lymph nodes: n/a | | |
| L. Total number of lymph nodes examined: 0 | | |
| M. Extracapsular spread of lymph node metastases: n/a | | |
| 1. Yes | 2. No | |
| N. Adrenal gland: | | |
| N1. Present 2 | 1. Yes | 2. No |
| N2. Involvement by renal neoplasm: 3 | 1. Yes | 2. No |
| N3. Other adrenal pathology: 3 | 1. Yes | 2. No |
| O. TNM stage: T 1b N x M x | | |

Source: NCI Genomic Data Commons file d3feb91b-f1fd-45e9-a1b9-182e7c36ab70 (TCGA-B0-5693.C53779B6-8163-41EF-82AF-ADB504DCBF3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).